Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEK-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Resection

Organs: Liver

[1] Segment 6: 14.0 x 5.5 x 4.5 cm, 133.0 gm

[2] Segment 8: 9.0 x 9.0 x 3.5 cm, 102.8 gm

Lesions: Multiple

[1] Segment 6

Size: 3.5 x 2.5 x 2.0 cm in toto

Cut surface: Well-defined, irregular shaped, whitish to brightly yellow, multinodular (the size does not contain a satellite mass measuring 1.3 x 1.0 cm, which is present at the nearby resection margin)

Resection margin: Very close grossly (safety margin: 0.1 cm)

[2] Segment 8

Size: 3.2 x 3.3 x 3.0 cm

Cut surface: Well-defined, ovoid, bulging-out, bile-tinged

Resection margin: Not involved grossly (safety margin: 1.2 cm)

Gross type:

[1] Segment 6: Multinodular confluent

[2] Segment 8: Expanding nodular

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, TB, irregular shaped mass and surrounding liver parenchyma of segment 6 x 5

A1-4, bile tinged mass and surrounding liver parenchyma of segment 8 x 4

L, NB, nontumorous liver parenchyma x 2

RM, resection margin of segment 6 x 1

ARM, resection margin of segment 8 x 1

MICROSCOPIC:

[1] Segment 6

Hepatocellular carcinoma: Yes

Edmondson-Steiner grade

worst: III

major: II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (10 %)

ICD-O-3

Carcinoma, hepatocellular NOS

8170/3

Site: Liver C22.0

QJ 5/20/14

[page 2 of 2]
Cholangiocarcinoma: No
Combined hepatocellular and cholangiocarcinoma: No
Fibrous capsule formation: No
Septum formation: No
Surgical resection margin invasion: Very close (less than 0.1 cm)

[2] Segment 8

Hepatocellular carcinoma: Yes
Edmondson-Steiner grade
worst: II
major: II
Histologic type: Trabecular
Cell type: Hepatic
Fatty change: Yes (10 %)
Cholangiocarcinoma: No
Combined hepatocellular and cholangiocarcinoma: No
Fibrous capsule formation: No
Septum formation: No
Surgical resection margin invasion: No

Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: No
Multicentric occurrence: Yes

Non-tumor liver pathology
Cirrhosis, mixed

NOT reported. Gross:

Liver, segment 6 and 8, resection, Hepatocellular carcinoma
T56000, segment 6 and 8, P17, M81703

DIAGNOSIS:

Liver, segment 6 and 8, resection: Hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file 637daec7-1302-4f3d-bffe-3698f00304f7 (TCGA-DD-AAEK.C174382E-E3FB-456E-B5B7-1949B3086967.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).